Gene-level copy-number profile of tumor specimen HCM-BROD-0793-C15-06A from HCMI case HCM-BROD-0793-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 55.2 years (20,179 days).
Specimen HCM-BROD-0793-C15-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 68ce6b6f-4f24-481e-8679-8b635d695a3f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0793-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/9ff4a3b3-7e0c-4f8f-95c0-3a22bdbdd91b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 553; copy number 1: 11,375; copy number 2: 36,982; copy number 3: 8,457; copy number 4: 620; copy number 5: 264; copy number 6: 30; copy number 7: 123; copy number 8: 40; copy number 9: 88; copy number 11: 26; copy number 12: 29; copy number 14: 3; copy number 15: 2; copy number 17: 10; copy number 18: 188; copy number 19: 2; copy number 20: 2; copy number 21: 14; copy number 22: 1; copy number 23: 8; copy number 24: 5; copy number 26: 49; copy number 27: 19; copy number 29: 6; copy number 34: 8; copy number 51: 4; copy number 55: 1.

Homozygous deletions (total copy number 0; autosomes only): 41 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:113,876,777–114,693,772, 7 genes (within-gene range 0–1): PPP1R3A, FOXP2, AC073626.2, AC073626.1, AC003992.1, RNA5SP238, MIR3666.
- chr16:68,636,189–68,835,541, 6 genes (within-gene range 0–2): CDH3, AC126773.4, AC126773.5, HSPE1P5, CDH1, RNA5SP429.
- chr16:78,550,739–78,553,296, 1 gene (within-gene range 0–1): AC046158.3.
- chr16:78,825,281–78,826,006, 1 gene (within-gene range 0–1): RPS3P7.
- chr18:50,879,080–53,581,107, 20 genes: ME2, Y_RNA, ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P, LINC01630, SS18L2P2, AC109315.1, RSL24D1P9, AC027216.1, RPS8P3, AC016383.1, DCC, AC011155.1, VN1R76P, MIR4528, LINC01917.
- chr18:54,587,757–54,599,493, 1 gene: DYNAP.
- chr18:57,646,426–58,019,061, 5 genes (within-gene range 0–1): ATP8B1, RNU6-742P, RSL24D1P11, LINC01897, HMGN1P30.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 922 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,403,964–2,505,532, 2 genes, copy number 5 (within-gene range 3–5): PEX10, PLCH2.
- chr1:2,581,560–2,636,620, 4 genes, copy number 5 (within-gene range 3–5): AL139246.3, PRXL2B, MMEL1, MMEL1-AS1.
- chr1:15,111,815–15,786,594, 31 genes, copy number 5 (within-gene range 3–5): TMEM51-AS1, TMEM51, C1orf195, MFFP1, ZBTB2P1, FHAD1, FHAD1-AS1, AL031283.2, AL031283.1, EFHD2, CTRC, CELA2A, CELA2B, CASP9, DNAJC16, SCARNA21B, AL121992.3, AGMAT, AL121992.1, CHCHD2P6, RNU7-179P, CD24P1, DDI2, RSC1A1, AL121992.2, PLEKHM2, AL450998.2, SLC25A34, SLC25A34-AS1, TMEM82, FBLIM1.
- chr2:81,194,337–81,201,184, 1 gene, copy number 7: ANKRD11P1.
- chr2:81,967,079–82,005,700, 2 genes, copy number 5: RN7SL201P, AC079896.1.
- chr5:33,424,025–38,468,339, 89 genes, copy number 5 (broad region; genes not listed).
- chr7:53,926,676–57,837,046, 143 genes, copy number 11–34 (broad region; genes not listed).
- chr7:87,109,539–94,834,447, 119 genes, copy number 5–6 (broad region; genes not listed).
- chr8:2,935,353–8,049,267, 122 genes, copy number 5–7 (broad region; genes not listed).
- chr8:8,086,022–8,116,949, 4 genes, copy number 7: AC105233.2, MIR548I3, RPS3AP31, SNRPCP17.
- chr8:8,701,937–12,665,588, 129 genes, copy number 8–11 (within-gene range 2–11) (broad region; genes not listed).
- chr9:61,659,733–61,662,690, 1 gene, copy number 5: AL935212.1.
- chr9:64,765,054–64,765,535, 1 gene, copy number 5: IGKV1OR-2.
- chr11:111,089,870–111,179,641, 5 genes, copy number 5: AP003973.2, LINC02550, AP003973.3, RPS17P15, AP003973.1.
- chr12:14,365,632–28,581,511, 225 genes, copy number 14–55 (broad region; genes not listed).
- chr15:21,298,233–21,325,241, 2 genes, copy number 9 (within-gene range 4–9): AC068446.2, RNU6-1235P.
- chr16:77,190,835–77,660,570, 9 genes, copy number 5: MON1B, SYCE1L, AC009139.2, VN2R10P, AC009139.1, ADAMTS18, AC025284.1, LINC02131, AC092724.1.
- chr18:22,933,349–23,982,556, 17 genes, copy number 7–29 (within-gene range 2–29): MIR4741, RN7SL745P, Y_RNA, CABLES1, TMEM241, AC011731.1, RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA, ANKRD29, RPS10P27, LAMA3, RPL23AP77, AC010754.1.
- chr18:38,655,209–40,144,504, 16 genes, copy number 5: AC100781.1, RN7SKP182, RNU6-706P, MIR924HG, AC011139.1, RPL7AP66, MIR924, AC099845.1, MIR5583-2, MIR5583-1, RNU6-1242P, LINC01901, LINC01902, AC011266.1, LINC01477, RPL17P45.

Autosomal genes at a single copy (total copy number 1): 9,031. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
